Gene-level copy-number profile of specimen HCM-CSHL-0184-C25-85A from HCMI case HCM-CSHL-0184-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.3 years (28,240 days).
Specimen HCM-CSHL-0184-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d812edfb-bf6f-4c7a-9888-c5fe53aa693b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0184-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/897ccb46-9842-4c16-96be-ddf84d96825f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 132; copy number 2: 11,107; copy number 3: 256; copy number 4: 29,722; copy number 5: 9,462; copy number 6: 6,090; copy number 7: 202; copy number 8: 193; copy number 9: 686; copy number 10: 348; copy number 11: 38; copy number 12: 12; copy number 15: 39; copy number 16: 11; copy number 22: 11; copy number 23: 21; copy number 24: 2; copy number 26: 22; copy number 27: 1; copy number 81: 20; copy number 109: 14.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,225 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:72,947,581–92,917,187, 319 genes, copy number 10–109 (within-gene range 6–109) (broad region; genes not listed).
- chr9:33,166,948–35,870,601, 144 genes, copy number 10–27 (within-gene range 2–27) (broad region; genes not listed).
- chr11:50,170,156–50,422,316, 9 genes, copy number 11: AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr12:166,856–1,647,212, 28 genes, copy number 9 (within-gene range 8–9): AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14.
- chr12:1,791,963–4,118,132, 61 genes, copy number 9 (broad region; genes not listed).
- chr12:6,199,715–6,451,718, 13 genes, copy number 9 (within-gene range 8–9): CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27.
- chr12:6,742,985–12,267,044, 261 genes, copy number 9 (broad region; genes not listed).
- chr12:12,974,870–19,376,400, 91 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr12:20,368,537–21,176,895, 9 genes, copy number 9 (within-gene range 7–9): PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1.
- chr12:22,063,773–22,437,041, 1 gene, copy number 9 (within-gene range 8–9): ST8SIA1.
- chr12:22,116,629–29,784,759, 128 genes, copy number 9 (broad region; genes not listed).
- chr12:30,306,065–30,879,268, 10 genes, copy number 9: AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44.
- chr12:31,073,860–32,340,724, 48 genes, copy number 9: DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, AC048344.4, AC026356.1.
- chr12:33,923,374–33,923,480, 1 gene, copy number 9: RNU6-472P.
- chr14:22,123,318–22,490,553, 46 genes, copy number 9–10: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr14:51,489,100–51,730,727, 1 gene, copy number 9 (within-gene range 8–9): FRMD6.
- chr14:51,637,348–52,069,228, 16 genes, copy number 9: AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2.
- chr14:59,429,022–61,083,733, 38 genes, copy number 10–12: GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6.

Autosomal genes at a single copy (total copy number 1): 132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
